Somatic mutation profile of tumor specimen 1105192 (aliquot 7316UP-287-1105192) from CPTAC case C224106, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105192: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d98c8b40-2481-48a2-9d10-15661503008a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105215 (Blood Derived Normal), aliquot 7316UP-287-1105215; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2fd3d9b-4a53-4ffd-b754-7a061018b3e4

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, In Frame Del 2, Intron 2, Nonsense Mutation 1, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB12 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748815216, COSV62857329; called by muse, mutect2, varscan2
- CDH18 | c.2184C>A p.S728R | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV56924162, COSV99935390; called by muse, mutect2, varscan2
- CXCR3 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs373077208; called by muse, mutect2, varscan2
- GDPD4 | c.1501_1504del p.F501Kfs*16 (on ENST00000376217; = p.F501Kfs*21 on NM_182833.3) | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | catalogued as rs774497362; called by mutect2, pindel, varscan2
- GTF3C5 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59599657; called by muse, mutect2, varscan2
- HRNR | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 145/296 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs148184849; called by muse, mutect2, varscan2
- LAMB1 | c.3037C>T p.R1013W | Missense Mutation (SNP) | VAF 136/462 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs767303427; called by muse, mutect2, varscan2
- LIPJ | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs781183196; called by muse, mutect2, varscan2
- NCBP1 | c.2341G>A p.V781M | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs377264051; called by muse, mutect2, varscan2
- OR10W1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs200070425, COSV67720621; called by muse, mutect2, varscan2
- OR52N1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs146336745; called by muse, mutect2, varscan2
- RAB44 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 136/325 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432024122; called by muse, mutect2, varscan2
- RASGRP2 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 132/365 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100818304, COSV62450841; called by muse, mutect2, varscan2
- SAMSN1 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756805588, COSV53478979; called by muse, mutect2, varscan2
- SMIM17 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs184713147; called by muse, mutect2, varscan2
- TRIM58 | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.482); catalogued as rs1011119348; called by muse, mutect2, varscan2
- TRIML1 | c.736-1G>A p.X246_splice | Splice Site (SNP) | VAF 50/163 reads (31%) | catalogued as COSV60195163; called by muse, mutect2, varscan2
- C16orf96 | c.1846C>A p.P616T | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CYB5R4 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- EDRF1 | c.716_719delinsG p.D239_S240delinsG | In Frame Del (DEL) | VAF 97/162 reads (60%) | called by pindel, varscan2*
- ENOSF1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 556/769 reads (72%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- FAM91A1 | c.1652T>G p.L551W | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L5 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HJURP | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ITSN2 | c.3655C>T p.Q1219* | Nonsense Mutation (SNP) | VAF 47/114 reads (41%) | called by muse, mutect2, varscan2
- KRT18 | c.1204A>C p.M402L | Missense Mutation (SNP) | VAF 145/391 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA1 | c.8509T>C p.Y2837H | Missense Mutation (SNP) | VAF 260/308 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMBRD1 | c.908_910del p.K303del (on ENST00000649011; = p.K281del on NM_018368.4) | In Frame Del (DEL) | VAF 85/256 reads (33%) | called by pindel, varscan2
- MGAM2 | c.4924G>A p.G1642R | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); called by muse, mutect2
- MRPL39 | c.628A>T p.I210F | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.381); called by muse, mutect2
- UTP20 | c.5422G>A p.V1808I | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKT1S1 | c.6G>A p.A2= (on ENST00000344175 / NM_001098633.4; = p.A22= on NM_032375.5) | Silent (SNP) | VAF 82/194 reads (42%) | catalogued as rs757867938; called by muse, mutect2, varscan2
- ARHGAP35 | c.1203G>T p.R401= | Silent (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2
- CD74 | c.138C>T p.R46= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as rs376043210; called by muse, mutect2, varscan2
- CSNK1D | c.861G>T p.V287= | Silent (SNP) | VAF 148/404 reads (37%) | called by muse, mutect2, varscan2
- FAM98C | c.933C>T p.N311= | Silent (SNP) | VAF 64/177 reads (36%) | catalogued as rs745545912, COSV53038483; called by muse, mutect2, varscan2
- KCNK6 | c.789C>T p.H263= | Silent (SNP) | VAF 117/307 reads (38%) | catalogued as rs200538663; called by muse, mutect2, varscan2
- LPAR3 | c.465C>T p.I155= | Silent (SNP) | VAF 75/207 reads (36%) | catalogued as rs565409119, COSV65452543; called by muse, mutect2, varscan2
- MGAT4D | c.750G>A p.K250= | Silent (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- NAV3 | c.2247G>A p.P749= | Silent (SNP) | VAF 83/211 reads (39%) | catalogued as rs367740483; called by muse, mutect2, varscan2
- OR2L5 | c.270T>C p.S90= | Silent (SNP) | VAF 110/250 reads (44%) | called by muse, mutect2, varscan2
- SCN2B | c.348C>T p.N116= | Silent (SNP) | VAF 298/715 reads (42%) | catalogued as rs72544144; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCRN1 | c.1161G>T p.L387= | Silent (SNP) | VAF 59/261 reads (23%) | called by muse, mutect2, varscan2
- ARPP19P2 | n.290A>G | RNA (SNP) | VAF 56/130 reads (43%) | catalogued as rs1320789244; called by muse, mutect2, varscan2
- ENTPD5 | c.218-185G>A | Intron (SNP) | VAF 56/135 reads (41%) | called by muse, mutect2, varscan2
- NXN | c.361-37938C>T | Intron (SNP) | VAF 91/267 reads (34%) | catalogued as rs74436197; called by muse, mutect2, varscan2
